Somatic mutation profile of tumor specimen TCGA-32-1970-01A (aliquot TCGA-32-1970-01A-01D-1494-08) from TCGA case TCGA-32-1970, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.2 years (21,613 days).
Specimen TCGA-32-1970-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80f639be-3085-412e-9181-ff237409b913.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-1970-10A (Blood Derived Normal), aliquot TCGA-32-1970-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85d307c7-1f44-48f2-8905-208394d4eb88

The open-access MAF lists 82 somatic variants for this specimen: 61 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 20, Nonsense Mutation 5, Frame Shift Del 1, Splice Region 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 1221/2266 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.800G>C p.R267P | Missense Mutation (SNP) | VAF 26/31 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587780075, CM921040, COSV52675189, COSV52691512, COSV52734317, COSV52740807; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACAP2 | c.134T>C p.M45T | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV58749185; called by muse, mutect2, varscan2
- ACTBL2 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.493); catalogued as rs756215581, COSV70660975; called by muse, mutect2, varscan2
- ASPM | c.9410C>A p.A3137D | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV54124335; called by muse, mutect2, varscan2
- AXIN2 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs771809149, COSV61055414; called by muse, mutect2, varscan2
- CCZ1 | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 46/426 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761962272, COSV100382890; called by muse, mutect2
- CDK13 | c.3088C>T p.Q1030* | Nonsense Mutation (SNP) | VAF 44/190 reads (23%) | catalogued as COSV51696300; called by muse, mutect2, varscan2
- CEL | c.1411G>A p.A471T (on ENST00000673714; = p.A468T on NM_001807.6) | Missense Mutation (SNP) | VAF 42/422 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs777913068, COSV60826235; called by muse, mutect2
- CEP104 | c.2715C>G p.S905R | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65516059; called by muse, mutect2, varscan2
- CEP128 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 71/187 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200105295, COSV53672384; called by muse, mutect2, varscan2
- CWF19L2 | c.2494G>A p.A832T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1293944790, COSV56508314; called by muse, mutect2, varscan2
- EGFL6 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 152/172 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs182977902, COSV63632763; called by muse, mutect2, varscan2
- EHD3 | c.976A>T p.N326Y | Missense Mutation (SNP) | VAF 17/260 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as COSV59029169; called by muse, mutect2
- ENPP2 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776304212, COSV50009900; called by muse, mutect2, varscan2
- F2RL3 | c.676G>A p.V226M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as rs769425674, COSV50185095; called by muse, mutect2, varscan2
- FAM71B | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs745867472, COSV57227431; called by muse, mutect2, varscan2
- FBXW11 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51605180; called by muse, mutect2, varscan2
- FFAR3 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 71/560 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as rs757551373, COSV59908663; called by muse, mutect2, varscan2
- FGB | c.489A>T p.K163N | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.019); catalogued as COSV57417424; called by muse, mutect2
- FLRT2 | c.608T>C p.L203P | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV58136045; called by muse, mutect2, varscan2
- GATM | c.108C>A p.F36L | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV67540101; called by muse, mutect2, varscan2
- GCA | c.110G>C p.G37A | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.169); catalogued as COSV52025032; called by muse, mutect2, varscan2
- GLS | c.735G>A p.K245= | Splice Region (SNP) | VAF 17/97 reads (18%) | catalogued as COSV57839796; called by muse, mutect2, varscan2
- GPR78 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs1244951368, COSV66762432; called by muse, mutect2, varscan2
- GRM3 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1363070278, COSV64467002; called by muse, varscan2
- GRM3 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 118/458 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV64467011; called by muse, varscan2
- HELZ2 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs748068037, COSV64409001; called by muse, mutect2, varscan2
- HRNR | c.845G>C p.S282T | Missense Mutation (SNP) | VAF 192/414 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs777994503, COSV64253956; called by muse, mutect2, varscan2
- ITIH5 | c.789C>A p.D263E | Missense Mutation (SNP) | VAF 126/165 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53659541; called by muse, mutect2, varscan2
- MAGI2 | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV62633216; called by muse, mutect2, varscan2
- MEGF11 | c.2837C>A p.T946K | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.261); catalogued as COSV56544427; called by muse, mutect2, varscan2
- OR4B1 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58881927; called by muse, mutect2, varscan2
- PCDHA2 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV65364430; called by muse, mutect2, varscan2
- PCLO | c.7709C>T p.P2570L | Missense Mutation (SNP) | VAF 100/444 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV61615127; called by muse, mutect2, varscan2
- PGPEP1L | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 79/181 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs372203076; called by muse, mutect2, varscan2
- POLD4 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56744483; called by muse, mutect2
- PRPF40B | c.1462C>T p.R488C (on ENST00000380281; = p.R482C on NM_012272.3) | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs781235317, COSV56057621; called by muse, mutect2, varscan2
- PRRC2B | c.3206G>A p.R1069H | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs377155180; called by muse, mutect2, varscan2
- PSPH | c.80G>C p.R27T | Missense Mutation (SNP) | VAF 989/3400 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV51908839; called by muse, varscan2
- PTGFR | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 133/269 reads (49%) | catalogued as rs750752823, COSV66114248, COSV66115158; called by muse, mutect2, varscan2
- RANBP17 | c.3220C>T p.R1074C | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs748673739, COSV66643784; called by muse, mutect2, varscan2
- RB1 | c.2336T>A p.L779* | Nonsense Mutation (SNP) | VAF 166/222 reads (75%) | catalogued as CS143547, COSV57295462; called by muse, mutect2, varscan2
- RBMS3 | c.1208C>G p.T403R (on ENST00000383767 / NM_001003793.3; = p.T387R on NM_014483.3) | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as rs143165101, COSV56131344; called by muse, mutect2, varscan2
- RNF31 | c.2762C>A p.S921Y | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV60725543; called by muse, mutect2
- SLC47A2 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 108/261 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148775490; called by muse, mutect2, varscan2
- SNX20 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs772636555, COSV56056544; called by muse, mutect2, varscan2
- SOX6 | c.2087G>A p.R696H (on ENST00000528429 / NM_001145819.2; = p.R669H on NM_017508.3) | Missense Mutation (SNP) | VAF 83/410 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57036569; called by muse, mutect2, varscan2
- STEAP1 | c.695T>C p.L232P | Missense Mutation (SNP) | VAF 94/423 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51880880; called by muse, mutect2, varscan2
- TMEM132B | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as rs868065390, COSV54744303; called by muse, mutect2, varscan2
- TMEM219 | c.400A>G p.T134A | Missense Mutation (SNP) | VAF 56/320 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV54243359; called by muse, varscan2
- TNFRSF8 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 45/94 reads (48%) | catalogued as rs148756853; called by muse, mutect2, varscan2
- TRAV20 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs369305527; called by muse, mutect2, varscan2
- TRIM58 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1277659091, COSV63569037, COSV63570091; called by muse, mutect2, varscan2
- UGGT1 | c.4157G>T p.C1386F | Missense Mutation (SNP) | VAF 94/224 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52132227; called by muse, mutect2, varscan2
- ZNF107 | c.599C>A p.A200D | Missense Mutation (SNP) | VAF 57/219 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs201135722, COSV61326756; called by muse, mutect2, varscan2
- ZNF229 | c.2036C>T p.T679M | Missense Mutation (SNP) | VAF 109/251 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as rs754516445, COSV52159418; called by muse, mutect2, varscan2
- ZNFX1 | c.1339C>T p.R447* | Nonsense Mutation (SNP) | VAF 64/330 reads (19%) | catalogued as COSV65573550; called by muse, mutect2, varscan2
- ANK1 | c.4841_4849del p.E1614_S1617delinsA | In Frame Del (DEL) | VAF 56/266 reads (21%) | called by mutect2, pindel, varscan2
- GEN1 | c.2515_2522delinsGAA p.K839Efs*2 | Frame Shift Del (DEL) | VAF 27/36 reads (75%) | called by mutect2*, pindel, varscan2*
- TRAF3 | c.1139T>C p.L380P | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- ADGRB1 | c.4515C>T p.H1505= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as rs757570335, COSV60091619; called by muse, mutect2, varscan2
- CCR9 | c.141G>A p.A47= (on ENST00000357632 / NM_031200.3; = p.A35= on NM_006641.4) | Silent (SNP) | VAF 106/240 reads (44%) | catalogued as rs372974725; called by muse, mutect2, varscan2
- CPNE2 | c.639C>T p.P213= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV51960785, COSV99321227; called by muse, mutect2, varscan2
- CYP2C18 | c.259C>T p.L87= | Silent (SNP) | VAF 136/180 reads (76%) | catalogued as COSV53669588; called by muse, mutect2, varscan2
- DHRS13 | c.402G>A p.A134= | Silent (SNP) | VAF 41/111 reads (37%) | catalogued as rs549688711, COSV60453041; called by muse, mutect2, varscan2
- DPH2 | c.963G>T p.R321= | Silent (SNP) | VAF 48/185 reads (26%) | catalogued as COSV52542460, COSV52542500; called by muse, mutect2, varscan2
- DPP10 | c.843G>A p.P281= | Silent (SNP) | VAF 108/278 reads (39%) | catalogued as rs146251151, COSV100071178; called by muse, mutect2, varscan2
- FRG2 | c.384C>G p.S128= | Silent (SNP) | VAF 70/162 reads (43%) | called by muse, mutect2, varscan2
- GRM3 | c.2088C>T p.I696= | Silent (SNP) | VAF 13/208 reads (6%) | catalogued as COSV64467018; called by muse, mutect2
- KRTAP4-5 | c.213T>C p.C71= | Silent (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- MRGPRX3 | c.93G>A p.T31= | Silent (SNP) | VAF 139/336 reads (41%) | catalogued as rs752591852, COSV66933165; called by muse, mutect2, varscan2
- MS4A3 | c.558C>T p.C186= | Silent (SNP) | VAF 157/442 reads (36%) | catalogued as rs778541342, COSV53934779; called by muse, mutect2, varscan2
- MTNR1B | c.471C>A p.T157= | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as COSV57065231; called by muse, mutect2, varscan2
- NEURL4 | c.4374C>T p.F1458= | Silent (SNP) | VAF 91/104 reads (88%) | catalogued as rs752327546, COSV59746958; called by muse, mutect2, varscan2
- OR13C9 | c.933G>A p.P311= | Silent (SNP) | VAF 132/424 reads (31%) | catalogued as rs761736284, COSV52240578; called by muse, mutect2, varscan2
- OR1S1 | c.165C>T p.N55= | Silent (SNP) | VAF 148/411 reads (36%) | catalogued as rs199668390, COSV58705936; called by muse, mutect2, varscan2
- OR2G6 | c.453C>T p.S151= | Silent (SNP) | VAF 44/89 reads (49%) | catalogued as rs774470186, COSV100598332, COSV58573644; called by muse, mutect2, varscan2
- OR2L3 | c.657G>T p.R219= | Silent (SNP) | VAF 82/260 reads (32%) | catalogued as COSV100742049, COSV63454392; called by muse, varscan2
- PCDHGB1 | c.252C>T p.N84= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as COSV53896243; called by muse, mutect2, varscan2
- STAB1 | c.1797G>A p.A599= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs778673205, COSV58731970; called by muse, mutect2, varscan2
- NACA | c.71-1199dup | Intron (INS) | VAF 50/171 reads (29%) | catalogued as rs1411787469; called by mutect2, pindel, varscan2
